Surgical pathology report (de-identified scan), TCGA case TCGA-10-0930, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-10-0930-01A (Primary Tumor).

[page 1 of 2]
████████████████████

████████████████████

████████████████████

DIAGNOSIS

- (A) OMENTUM:
HIGH GRADE SEROUS CARCINOMA.
- (B) PORTION OF LEFT OVARIAN TUMOR:
HIGH GRADE SEROUS CARCINOMA.
- (C) LEFT OVARY AND FALLOPIAN TUBE:
OVARIAN HIGH GRADE SEROUS CARCINOMA.
CARCINOMA INVOLVES TUBAL SEROSA.
- (D) UTERUS, RIGHT OVARY AND FALLOPIAN TUBE:
Endocervical polyp.
Atrophic endometrium with adenomyosis.
Myometrial leiomyomata.
Ovary and fallopian tube, no tumor present.
- (E) RIGHT PERIVAGINAL CYST WALL:
Fragments of HIGH GRADE SEROUS CARCINOMA, fibrosis and granulation tissue.
- (F) CUL-DE-SAC TUMOR:
HIGH GRADE SEROUS CARCINOMA.
- ██
- ██
- ██

GROSS DESCRIPTION

(A) OMENTUM – Fragment of fibroadipose tissue (24.0 cm x 11.0 cm x 1.5 cm). Multiple nodules varying in size from 8.5 to 1.5 to 2.0 cm to 1.5 x 1.0 x 1.0 cm in greatest dimension, are embedded in the omental fat. They are firm and rubbery, poorly circumscribed with fibrous septa diffusely penetrating into the fat. Representative sections are submitted.

SECTION CODE: A1-A7, omental nodules; A8, unremarkable adipose tissue. Fragments from the unremarkable fat and tumor are submitted for research. ██████████

(B) PORTION OF LEFT OVARIAN TUMOR – Well-circumscribed mass (2.7 x 1.5 x 1.0 cm). Red-white, fleshy, partially hemorrhagic. One representative section is submitted for frozen section.

SECTION CODE: B1, frozen section one piece, two representative sections from the tumor; B2, B2, representative section. Fragments are submitted for research. ██████████

*FS/DX: HIGH-GRADE SEROUS CARCINOMA. ██████████

(C) LEFT TUBE AND OVARY – The specimen consists of an unremarkable left tube (9.5 cm in length x 1.0 cm in diameter) and an opened cystic ovary (11.0 x 8.0 x 4.0 cm). The external surface of the cyst is smooth. The internal surface is smooth in places but in others a friable, tan-pink, papillary mass is present and fills the entire cavity. Some smaller cysts are present containing clear, serous fluid and smooth internal lining. Included are fragmented portions of tumor (5.0 x 5.0 x 1.5 cm in aggregate). No normal ovarian tissue can be identified.

SECTION CODE: C1, fallopian tube; C2, cyst wall with smooth internal lining; C3-C16, samples of tumor and cyst wall.

██████████

(D) UTERUS, CERVIX, RIGHT TUBE AND OVARY – Consists of a uterus 13.0 x 7.0 x 6.0 cm, cervix 5.0 cm in length x 3.0 cm in diameter, unremarkable right ovary 3.5 x 2.0 x 1.5 cm, and unremarkable fallopian tube (9.0 cm in length x 0.8 cm in diameter). A large leiomyoma with whorled, red cut surface 5.0 x 5.0 x 4.0 cm is located in the fundus. This nodule distorts the uterine cavity which measures 9.0 cm in maximum dimension and is represented mostly by anterior endometrial wall. Numerous leiomyomas are present submucosally ranging in size from 0.1 to 1.5 cm in greatest diameter, with a whorled, firm, gray cut surface. A cervical

[page 2 of 2]
[REDACTED]

polyp is present in the anterior cervix (1.6 cm in diameter). The cervical wall is 2.5 cm maximum thickness. No other lesions are present in the endometrium.

SECTION CODE: D1, right ovary; D2, right tube; D3, cervical polyp; D4, cervix at 3 o'clock; D5, cervix at 9 o'clock; D6, anterior endometrium; D7, posterior endometrium; D8-D10, largest nodule; D11, D12, smaller nodules. [REDACTED]

(E) RIGHT PERIVAGINAL CYST WALL – Consists of a portion of tan-brown tissue measuring (2.0 x 1.0 x 0.4 cm) entirely submitted.

SECTION CODE: Cassette E, submitted in toto. [REDACTED]

(F) CUL-DE-SAC TUMOR - A portion of tan-brown tissue (2.0 x 1.0 x 0.8 cm). Bisected and submitted entirely.

SECTION CODE: F, specimen in toto. [REDACTED]

CLINICAL HISTORY

Pelvic mass.

[REDACTED]

[REDACTED]

-----END OF REPORT-----

[REDACTED]

Source: NCI Genomic Data Commons file 47d17a64-61d3-41c4-adac-5143553a436c (TCGA-10-0930.89034658-E10D-47D3-9AD8-D79AA51CF234.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).